Gene-level copy-number profile of tumor specimen HTMCP-01-06-00306-01A from CGCI case HTMCP-01-06-00306, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS.
Specimen HTMCP-01-06-00306-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c7c3a3fc-db59-4454-aa2d-77207056a903.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00306-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/e17150c4-5032-419b-b68e-eb85dfc64496

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 41; copy number 2: 300; copy number 3: 471; copy number 4: 40,058; copy number 5: 2,579; copy number 6: 14,471; copy number 7: 317; copy number 13: 3; copy number 16: 17; copy number 18: 71.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,425,980–5,090,899, 58 genes: PLCH2, AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B, MMEL1, MMEL1-AS1, TTC34, AC242022.2, AC242022.1, AL592464.2, AL592464.3, AL592464.1, ACTRT2, PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2, TP73-AS1, AL136528.1, CCDC27, SMIM1, LRRC47, RN7SL574P, AL365330.1, CEP104, DFFB, C1orf174, LINC01134, LINC01346, LINC01345, EEF1DP6, LINC01777, Z98747.1, LINC01646, AJAP1, Z98886.1, LINC02782.
- chr14:105,647,924–105,673,314, 3 genes (within-gene range 0–2): COPDA1, IGHGP, ELK2AP.
- chr14:105,721,794–105,722,527, 1 gene (within-gene range 0–2): IGHEP1.
- chr14:106,377,300–106,411,021, 5 genes (within-gene range 0–2): IGHV7-34-1, IGHV3-35, IGHV3-36, IGHV3-37, IGHV3-38.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 91 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:59,434,552–62,533,059, 69 genes, copy number 18 (broad region; genes not listed).
- chr2:62,552,463–62,561,423, 2 genes, copy number 18: PSAT1P2, RSL24D1P2.
- chr2:91,578,478–91,621,421, 3 genes, copy number 13 (within-gene range 6–13): AC233266.1, AC233266.2, AC116050.1.
- chr2:91,674,857–92,035,000, 17 genes, copy number 16: RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3, GGT8P, IGKV1OR2-1, ABCD1P5, AC127391.1, PABPC1P6, SLC9B1P2, ACTR3BP2, CHEK2P3, AC128677.1, IGKV1OR2-2.

Autosomal genes at a single copy (total copy number 1): 41. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
